Surgical pathology report (de-identified scan), TCGA case TCGA-AA-A00O, project TCGA-COAD (Colon Adenocarcinoma), tissue source site Indivumed, specimen TCGA-AA-A00O-01A (Primary Tumor).

ICD-0-3

adenocarcinoma, NOS 8140/3

Site: sigmoid (pw CQCF) C18.7 Ju 3/29/11

Sample ID #

Diagnosis:

Resectate of the large intestine under inclusion of a centrally ulcerated, poorly differentiated adenocarcinoma of the colorectal type and of max. 4.5 cm in diameter, with broad infiltration of the pericolic fatty tissue, extensive lymphangiosis carcinomatosa and thirty-two regional lymph node metastases. Tumor-free large intestinal resection margins. Tumor-free mesenteric resection margin.

Tumor stage: pT3 pN2 (32/40) pMX; G3; L1, V0, RX

Reviewed Initials	ju	5/16/11

Source: NCI Genomic Data Commons file 74acde75-6b7c-4a95-a0ad-8b0f8a898571 (TCGA-AA-A00O.D60FE415-7BE3-49B6-802C-EAF36A583E28.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).